Gene-level copy-number profile of tumor specimen HCM-SANG-0519-C20-01A-01D-A80T-32 from HCMI case HCM-SANG-0519-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectum, NOS; Tumor grade: G3.
Specimen HCM-SANG-0519-C20-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b3eeaa18-4463-443c-860f-dd9251c77921.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0519-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/f91a8097-9dfe-4cc6-b908-e0bf6ad98950

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 17; copy number 2: 13,879; copy number 3: 1,513; copy number 4: 36,719; copy number 5: 3,150; copy number 6: 2,902; copy number 7: 205; copy number 8: 6.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:130,529,419–130,598,779, 2 genes: ARL2BPP4, AC005741.1.
- chr20:25,195,693–25,298,012, 8 genes (within-gene range 0–2): ENTPD6, Y_RNA, AL035252.4, AL035252.3, AL121772.1, PYGB, AL121772.2, AL121772.3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 17. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
